Surgical pathology report (de-identified scan), TCGA case TCGA-VQ-A91U, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Barretos Cancer Hospital, specimen TCGA-VQ-A91U-01A (Primary Tumor).

Collect date.

ICD-0-3
Adenocarcinoma, intestinal
814413
Site Gastroesophageal
junction C6.0
JW 3/13/14

PATHOLOGY REPORT:

PRIMARY SITE: Stomach (Gastroesophageal junction)

1-Stomach + greater omentum + distal esophagus:

Moderately differentiated adenocarcinoma, intestinal Lauren pattern (size: 9.5cm),
infiltrating to subserosa.

Foci of vascular invasion present.

Proximal and distal surgical margins uninvolved by neoplasia.

Metastasis in 2 perigastric lymph nodes (2/24).

Omentum uninvolved by neoplasia.

Pathologic stage: pT3 pN1.

2-Esophageal margin:

Uninvolved by neoplasia.

Absence of squamous epithelium in this sample.

3-Duodenal margin:

Uninvolved by neoplasia.

Uniqueness Discrepancy		
ICD-0 Discrepancy		
Discrepancy between Primary/Noted		

Source: NCI Genomic Data Commons file d73f4a03-678e-44d2-aabf-16d35d5c389d (TCGA-VQ-A91U.24F2F3AA-430A-462A-AB1D-D02368297EE0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).